Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A6X4, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A6X4-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: M

Age:

Date of surgery:

Localization: L temporal

Diagnosis: Anaplastic oligoastrocytoma (grade III WHO)

Name of Pathologist:

ICD-3
Oligoastrocytoma, grade III
9382/3
Site Brain, supratentorial NOS
C71.0
JW 8/12/13

Source: NCI Genomic Data Commons file 0868d55a-adba-4c94-80e3-2e30f6d569af (TCGA-QH-A6X4.638A5F85-FA2A-4E1D-B1BC-DC1922E9BAD9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).